Somatic mutation profile of tumor specimen TCGA-28-5219-01A (aliquot TCGA-28-5219-01A-01D-1486-08) from TCGA case TCGA-28-5219, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.2 years (17,254 days).
Specimen TCGA-28-5219-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 993f453f-4ec6-44bb-9390-c729d9fa63f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5219-10A (Blood Derived Normal), aliquot TCGA-28-5219-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d0cbc4-ce38-47ce-a99d-2f3021aee987

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Frame Shift Ins 2, Frame Shift Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 66/97 reads (68%) | hotspot (GDC flag); catalogued as CS167193, COSV52662718, COSV52757202, COSV53162510; called by muse, mutect2, varscan2
- AHR | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 81/399 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757131411, COSV54122212; called by muse, mutect2, varscan2
- AP4M1 | c.827A>T p.Q276L | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV57994513; called by muse, mutect2
- C20orf85 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs868284237, COSV64519111; called by muse, mutect2, varscan2
- CCER1 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62646213, COSV62647243; called by muse, mutect2, varscan2
- DNAH7 | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs534363346, COSV56755548; called by muse, mutect2, varscan2
- FKBP8 | c.901C>T p.H301Y (on ENST00000222308 / NM_001308373.2; = p.H302Y on NM_012181.5) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55891280; called by muse, mutect2, varscan2
- GABRD | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562124721, COSV66080034; called by muse, mutect2, varscan2
- GTF3C1 | c.3535G>C p.G1179R | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); catalogued as COSV62239562; called by muse, mutect2, varscan2
- HS3ST1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV50023165, COSV99136666; called by muse, mutect2, varscan2
- KMT2C | c.3767C>G p.A1256G | Missense Mutation (SNP) | VAF 78/437 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV51405757; called by muse, mutect2, varscan2
- KRT18 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV66315944; called by muse, mutect2, varscan2
- NAV1 | c.5240C>T p.S1747L | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV55214983; called by muse, mutect2, varscan2
- ODAM | c.62A>T p.Q21L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV68572386; called by muse, mutect2, varscan2
- PCDHA1 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as rs1554118218, COSV65373104; called by muse, mutect2, varscan2
- PCLO | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 64/490 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV61621841; called by muse, mutect2, varscan2
- PDE6B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.079); catalogued as rs751982910, COSV55324639; called by muse, varscan2
- PNPLA7 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747391094, COSV52994460; called by muse, mutect2, varscan2
- POLR1A | c.2960A>G p.Y987C | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55690263; called by muse, mutect2
- PRAME | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs116965324, COSV67161168; called by muse, mutect2, varscan2
- REPIN1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs963419117, COSV68291984; called by muse, mutect2
- RERE | c.386A>C p.D129A | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61938407, COSV61952139; called by muse, mutect2, varscan2
- RYR2 | c.11710C>T p.R3904W | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs998659755, COSV100773660, COSV63670026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC44A4 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs745490493, COSV57666350; called by muse, mutect2, varscan2
- SUSD5 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs372702857; called by muse, mutect2, varscan2
- TEX30 | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs1192014727, COSV65696464; called by muse, mutect2, varscan2
- TTN | c.66985C>T p.R22329W (on ENST00000591111; = p.R14905W on NM_003319.4) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | PolyPhen probably damaging (0.999); catalogued as rs748041610, COSV59932620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.50429G>T p.R16810L (on ENST00000591111; = p.R9386L on NM_003319.4) | Missense Mutation (SNP) | VAF 62/197 reads (31%) | PolyPhen probably damaging (0.998); catalogued as COSV59877034, COSV59932648; called by muse, mutect2, varscan2
- TWNK | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 121/203 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV52966275; called by muse, mutect2, varscan2
- UGT2A1 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54139168; called by muse, mutect2, varscan2
- ZCCHC13 | c.297T>A p.H99Q | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59866015; called by muse, mutect2, varscan2
- ZNF618 | c.1397G>A p.R466Q (on ENST00000374126 / NM_001318042.2; = p.R373Q on NM_133374.2) | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs371074016; called by muse, mutect2, varscan2
- AKAP9 | c.7302del p.F2435Sfs*2 (on ENST00000359028; = p.F2411Sfs*2 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | called by mutect2, pindel, varscan2
- CDC73 | c.243_249dup p.P84Kfs*6 | Frame Shift Ins (INS) | VAF 32/108 reads (30%) | called by mutect2, varscan2
- GLI2 | c.2148del p.K717Rfs*63 (on ENST00000361492 / NM_001374353.1; = p.K734Rfs*63 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- JAK1 | c.3178_3179dup p.A1061Lfs*16 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.1833A>T p.G611= | Silent (SNP) | VAF 53/169 reads (31%) | catalogued as COSV52665058; called by muse, mutect2, varscan2
- COL19A1 | c.333C>T p.N111= | Silent (SNP) | VAF 78/256 reads (30%) | catalogued as rs143252227; called by muse, mutect2, varscan2
- MAGEA12 | c.549C>T p.G183= | Silent (SNP) | VAF 21/360 reads (6%) | catalogued as COSV63294330; called by muse, mutect2
- MBD3 | c.780G>A p.A260= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs150880184; called by muse, mutect2, varscan2
- NFKBIB | c.870C>T p.A290= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs1483169010, COSV58003080; called by muse, mutect2, varscan2
- NOTCH3 | c.5145G>A p.G1715= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV54629070; called by muse, mutect2, varscan2
- RIPK4 | c.2037C>T p.N679= (on ENST00000352483; = p.N631= on NM_020639.3) | Silent (SNP) | VAF 108/155 reads (70%) | catalogued as rs781171886, COSV60186148; called by muse, mutect2, varscan2
- SEMA3D | c.873A>G p.G291= | Silent (SNP) | VAF 174/837 reads (21%) | catalogued as COSV52389335; called by muse, mutect2, varscan2
- STAB1 | c.4473C>T p.D1491= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs373996604; called by muse, mutect2, varscan2
- TLR3 | c.645G>A p.G215= | Silent (SNP) | VAF 19/322 reads (6%) | called by muse, mutect2
- MBNL1 | c.174+40376A>G | Intron (SNP) | VAF 31/117 reads (26%) | catalogued as COSV56825205; called by muse, mutect2, varscan2
